MMRF case MMRF_2538 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b2368a3a-0df8-4147-8a35-cad34f7df133

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.5 years (25,037 days); ISS stage: II; Days to last known disease status: 613 days (1.7 years); Days to last follow up: 613 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 77 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 92 days; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Lenalidomide + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 162 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 613.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 2): M Protein 3.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 26.9 g/L; Immunoglobulin M 1.31 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.46 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 33 g/L; Total Protein 8.9 g/dL; Glucose 5.45 mmol/L; C-Reactive Protein 0.85 mg/dL.
- Day 82 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 7.77 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.75 g/L; Beta 2 Microglobulin 2.15 µg/mL; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 45 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 5.7 g/dL; Glucose 5.89 mmol/L.
- Day 187 (ECOG 1): Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.61 mmol/L.
- Day 305: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 6.85 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 1.19 g/L; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 1.7 ×10⁹/L; Absolute Neutrophil 0.83 ×10⁹/L; Platelets 67 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 5.4 g/dL; Glucose 5.78 mmol/L.
- Day 327 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.07 mg/dL; Immunoglobulin G 7.5 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 1.26 g/L; Beta 2 Microglobulin 2.09 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 5.7 g/dL; Glucose 4.84 mmol/L.
- Day 414: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.36 mg/dL; Immunoglobulin G 6.84 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 1.72 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 55 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 5.4 g/dL; Glucose 5.12 mmol/L.
- Day 502 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.5 mg/dL; Immunoglobulin G 7.21 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 1.79 g/L; Beta 2 Microglobulin 2.07 µg/mL; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 23 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 5.1 g/dL; Glucose 4.68 mmol/L.

Other clinical attributes
- Day -10: Weight: 101 kg; Height: 189 cm.

Biospecimens (2 samples)
- Sample MMRF_2538_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_2538_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
